Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6339, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6339-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. RIGHT PELVIC LYMPH NODES
- B. LEFT PELVIC LYMPH NODES
- C. PROSTATE

SPECIMEN(S):

- A. RIGHT PELVIC LYMPH NODES
- B. LEFT PELVIC LYMPH NODES
- C. PROSTATE

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

- A) Lymph node, right pelvic:
- Four benign lymph nodes (0/4) by Dr.
- Diagnosis called to [REDACTED]
- B) Lymph nodes, left pelvic, biopsy:
- Two benign lymph nodes (0/2) by Dr.
- Diagnosis called to [REDACTED]

GROSS DESCRIPTION:

A. RIGHT PELVIC LYMPH NODES:

Received fresh labeled with the patient name labeled "lymph node right pelvic" is a portion of red-yellow adipose tissue measuring 6 x 3 x 1 cm. Multiple possible lymph nodes are identified measuring 1.2 x 0.7 x 0.3 cm, 0.6 x 0.4 x 0.2 cm, 1.5 x 0.7 x 0.5, and 1.5 x 0.6 x 0.4 cm. All four possible lymph nodes are bisected. Touch prep performed. All four lymph nodes are submitted for frozen section in cassette FSA1 and FSA2.

B. LEFT PELVIC LYMPH NODES:

Received fresh labeled with the patient's name designated "B - left pelvic lymph node" is a portion of red-yellow adipose tissue measuring 2.9 x 2 x 1.5 cm. Two possible lymph nodes are identified measuring 3 x 1.5 x 1 cm, and 4 x 1 x 0.5 cm. Both lymph nodes are serially sectioned. Touch prep performed. Both lymph nodes are entirely submitted for frozen section in cassette FSB1 and FSB2.

C. PROSTATE:

Received fresh labeled with patient name designated "C - prostate" is a resected prostate gland weighing 34 grams and measuring 4 cm. from right to left, 3.5 cm. from anterior to posterior, and 2.2 cm. from apex to base. The external capsule is smooth, red and intact. The specimen is inked as follows: apex-red, anterior-orange, base-blue, posterior-black, right-green, left-yellow. The apex and base are disassembled from the specimen to yield a new weight of 18 grams. The specimen is serially sectioned from apex to base. Cut section shows firm tan fibrous parenchyma with no obvious lesions or nodules. The right and left seminal vesicle measure 1.5 x 1.4 x 0.6 cm. and 1.3 x 1.3 x 0.5 cm. respectively. Both are bisected to show beige-tan tissue. The right and left vas measure 1.5 cm. in length by 0.5 cm. in diameter and 2 cm. in length by 0.5 cm. in diameter respectively. Both are serially sectioned to show firm tan tube structure. A portion of the specimen is submitted for tissue procurement. The remainder is entirely submitted for microscopic evaluation. Cassettes are submitted as follows;

- C1-C2: right apex
- C3: left apex
- C4: level 1 capsule right side
- C5: level 1 capsule left side
- C6: level 2 capsule right side
- C7: level 2 capsule left side
- C8: level 3 right anterior
- C9: level 3 right posterior
- C10: level 3 left anterior
- C11: level 3 left posterior
- C12: right lateral base
- C13-C14: right base with proximal urethral margin and root of right seminal vesicle
- C15-C16: left base with proximal urethral margin
- C17: left base
- C18-C19: left lateral base
- C20: representative serial sections right vas
- C21: representative serial sections left vas

[page 2 of 2]
DIAGNOSIS:

A. LYMPH NODES, RIGHT PELVIC, DISSECTION:
- FOUR BENIGN LYMPH NODES (0/4).

B. LYMPH NODES, LEFT PELVIC, DISSECTION:
- TWO BENIGN LYMPH NODES (0/2).

C. PROSTATE, RADICAL PROSTATECTOMY:
- PROSTATE ADENOCARCINOMA, GLEASON'S GRADE 3+4 (7/10), INVOLVING
APPROXIMATELY 25% OF PROSTATIC TISSUE.
- EXTRAPROSTATIC EXTENSION, LYMPHOVASCULAR AND BILATERAL
SEMINAL VESICLE INVOLVEMENT IS IDENTIFIED.
- SURGICAL MARGINS ARE NOT INVOLVED

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: RIGHT PELVIC LYMPH NODES

B: LEFT PELVIC LYMPH NODES

C: PROSTATE

Location: Left

Right

Posterior lateral

Apical

Basal

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 25%

Gleason Grade/Sum:: Grade 3 + 4 , Sum 7

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: Yes

Seminal Vesicle Invasion: Yes

Left

Right

Muscular Wall Invasion: Yes

Lumen Invasion: No

Periprostatic Fat Involved: No

Bladder Neck Involved: No

Margins Involvement: No

Frozen Performed: Yes

Post Hormonal Therapy Change: No

Lymph Nodes: Negative Right 0 / 4 Left 0 / 2

Other Pathologic Findings: None identified

Pathological Staging (pTNM): T 3b N 0 M x

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer

Source: NCI Genomic Data Commons file 27c61efc-91d0-4b25-950a-a352994c5b58 (TCGA-G9-6339.10FA561E-76C7-4F83-BC1C-B858DF9CCC46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).